Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M3, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M3-01A (Primary Tumor).

Operative Procedure:

Median sternotomy thymectomy

Pre-Operative Diagnosis:

As below

Post-Operative Diagnosis:

As below

Specimen(s) Received:

Thymus (Fresh tissue)

Final Pathologic Diagnosis:

Thymus, thymectomy:

Invasive thymoma, predominantly epithelial, with lymphatic involvement. B3 pw TSS

This case material was reviewed by the pathologist of record and represents the diagnosis of the staff pathologist.

Gross Description:

Received fresh and subsequently submitted in formalin is a specimen labeled with the patient's name and "thymus." The specimen consists of a 160 gram piece of fatty and soft tissue that is 20 x 11 x 2 cm. There is a somewhat well-defined 6 x 5.5 x 2.5 cm mass. The specimen is step-sectioned to reveal a fairly well defined somewhat encapsulated 5.5 x 5 x 2.5 cm mass. On step-sectioning this is tan and fleshy. Samples are submitted in six cassettes.

Microscopic Description:

The mass is encapsulated and consists of sheets of polygonal cells with occasional mitosis and foci of squamoid differentiation, divided by hyalinized fibrous septa. Perivascular edema is present. Foci of extracapsular invasion and lymphatic vessel involvement are found. Tumor focally approaches closely to the inked resection margin.

Surgical Pathology Report

Taken: DOB: (Age: Gender: F

CECE ICD O3
Thymoma, type B3, malignant 8585/3
path Thymoma NOS, malignant 8580/3
Site: Thymus C379
9/26/10/14

RFA Discrepancy		☒
Prior Malignant Tumor		☒
Qual/Synch/Cons Primary Site		☒
Case is (re)re: QUALIFIED		
Reviewed Initials: SC		

Source: NCI Genomic Data Commons file 90797b0f-75b9-4c51-b75e-ca838529b013 (TCGA-X7-A8M3.B65881FB-2D0D-4633-AFA5-54DA370150CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).